Somatic mutation profile of tumor specimen MMRF_1309_1_BM_CD138pos (aliquot MMRF_1309_1_BM_CD138pos_T1_KBS5U_L02848) from MMRF case MMRF_1309, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 83.7 years (30,580 days).
Specimen MMRF_1309_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46771480-91c3-4568-a608-da9f44d52b5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1309_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1309_1_PB_Whole_C3_KBS5U_L02860; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12c33fb4-4ade-4f4b-b722-f00421a44ebd

The open-access MAF lists 140 somatic variants for this specimen: 59 protein-altering or splice-affecting, 17 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, 3'UTR 38, Intron 17, Silent 17, 5'Flank 5, 5'UTR 2, RNA 2, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACBD4 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs747689259; called by muse, mutect2, varscan2
- ADAMTS16 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs758166784, COSV56995114; called by muse, mutect2, varscan2
- ARFGEF3 | c.3464C>T p.S1155F | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV99292222; called by muse, mutect2, varscan2
- BMPR2 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV101001402; called by muse, mutect2
- BRINP3 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 89/300 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as COSV66527581; called by muse, mutect2, varscan2
- COL6A1 | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs753485651, COSV62612049; called by muse, mutect2, varscan2
- DNAH5 | c.10577C>A p.A3526D | Missense Mutation (SNP) | VAF 21/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54248036; called by muse, mutect2
- DPYSL3 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs781130845, COSV58327316; called by muse, mutect2, varscan2
- DSP | c.7193A>G p.N2398S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs1251606363; called by muse, mutect2, varscan2
- FARS2 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375460524, COSV51172566, COSV51176224; called by muse, mutect2, varscan2
- GPC5 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs868574650; called by muse, mutect2, varscan2
- HOXB4 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.548); catalogued as COSV60177922; called by muse, mutect2, varscan2
- IGLL5 | c.181T>G p.S61A | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs939720182; called by muse, varscan2
- IGLV2-8 | c.218G>C p.S73T | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs11558646; called by muse, mutect2, varscan2
- IGLV3-25 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 97/220 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.227); catalogued as rs1224954062; called by muse, varscan2
- IPO13 | c.2794C>T p.R932C | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs770488466; called by muse, mutect2, varscan2
- IQGAP3 | c.4411C>T p.R1471C | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs748938834, COSV100752483; called by muse, mutect2, varscan2
- MFAP3L | c.343del p.V115Yfs*20 | Frame Shift Del (DEL) | VAF 48/152 reads (32%) | catalogued as COSV64371813; called by mutect2, pindel*, varscan2
- MYO10 | c.3235G>A p.A1079T | Missense Mutation (SNP) | VAF 67/253 reads (26%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs775296512; called by muse, mutect2, varscan2
- NKTR | c.1015A>G p.I339V | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.523); catalogued as rs937651215; called by muse, mutect2, varscan2
- OSBPL1A | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs1197146685; called by muse, mutect2, varscan2
- OTOF | c.4991C>T p.A1664V (on ENST00000272371 / NM_194248.3; = p.A897V on NM_004802.4) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs1410079943, COSV55519537, COSV99718187; called by muse, mutect2, varscan2
- PCDHA13 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as rs782045843, COSV56519550; called by muse, mutect2, varscan2
- PPP1R13L | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779760960, COSV100714662; called by muse, mutect2, varscan2
- ROBO1 | c.2578T>G p.S860A | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs765830793; called by muse, varscan2
- SBF1 | c.3562C>T p.R1188C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100818126; called by muse, mutect2, varscan2
- SUSD2 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778152993; called by muse, mutect2, varscan2
- TTC33 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs751422389, COSV61802488; called by muse, mutect2, varscan2
- WDR64 | c.827A>G p.H276R | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750575442; called by muse, mutect2, varscan2
- AMOTL2 | c.1716G>T p.K572N | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BUB1 | c.3216G>C p.R1072S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC73 | c.657dup p.A220Sfs*15 | Frame Shift Ins (INS) | VAF 12/35 reads (34%) | called by mutect2, varscan2
- CNOT3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CORO1A | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DLD | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 21/309 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- ECT2 | c.1414G>C p.A472P (on ENST00000392692 / NM_001349098.2; = p.A441P on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.334); called by muse, mutect2
- EDEM1 | c.418T>C p.F140L | Missense Mutation (SNP) | VAF 103/235 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- FAM210B | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 129/282 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GDF9 | c.628A>G p.K210E | Missense Mutation (SNP) | VAF 87/284 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- HIVEP3 | c.4282A>G p.S1428G | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- HNRNPAB | c.448_450del p.K150del | In Frame Del (DEL) | VAF 16/67 reads (24%) | called by pindel, varscan2
- IGKV2-24 | chr2:89176326 del TGAGGA | Missense Mutation (DEL) | VAF 22/29 reads (76%) | called by mutect2, pindel, varscan2
- KLHL38 | c.1337T>C p.V446A | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MYO7B | c.5268C>G p.D1756E | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PAN3 | c.1498T>A p.F500I | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PTPRN2 | c.1739A>T p.K580I | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2
- RILPL2 | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SDK2 | c.4478C>T p.S1493L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAPT1 | c.335T>A p.M112K | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- THSD7B | c.3958G>T p.D1320Y (on ENST00000272643; = p.D1318Y on NM_001316349.2) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TTN | c.71822C>T p.T23941I (on ENST00000591111; = p.T16517I on NM_003319.4) | Missense Mutation (SNP) | VAF 133/272 reads (49%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VPS13D | c.952T>A p.W318R | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZIK1 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ZNF107 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF17 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF276 | c.1006+1G>A p.X336_splice (on ENST00000443381 / NM_001113525.2; = p.X261_splice on NM_152287.4) | Splice Site (SNP) | VAF 25/28 reads (89%) | called by muse, mutect2, varscan2
- ZNF529 | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2
- ZNF563 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 106/308 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF653 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, varscan2
- ABCC8 | c.1791C>T p.V597= | Silent (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- ARID5B | c.175C>T p.L59= | Silent (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- AZGP1 | c.564G>A p.A188= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as rs375811707; called by muse, mutect2, varscan2
- CACNG6 | c.163C>T p.L55= | Silent (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- CLPS | c.78C>T p.I26= | Silent (SNP) | VAF 26/200 reads (13%) | catalogued as rs1482413707; called by muse, mutect2, varscan2
- FZD7 | c.363T>C p.R121= | Silent (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- IFITM1 | c.378G>A p.*126= | Silent (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- IGFL1 | c.285C>T p.C95= | Silent (SNP) | VAF 92/291 reads (32%) | catalogued as rs370059487; called by muse, mutect2, varscan2
- MAP3K14 | c.159A>T p.G53= | Silent (SNP) | VAF 40/202 reads (20%) | catalogued as COSV60923851; called by muse, varscan2
- PCDHGA1 | c.2289G>A p.S763= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as COSV65296482; called by muse, mutect2, varscan2
- PDGFC | c.735A>G p.V245= | Silent (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- PITPNM1 | c.2079C>T p.F693= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV62709371; called by muse, mutect2, varscan2
- PRKAG3 | c.510G>T p.L170= | Silent (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- PRR23B | c.354G>A p.S118= | Silent (SNP) | VAF 46/92 reads (50%) | catalogued as COSV61493585; called by muse, mutect2, varscan2
- SHISA7 | c.1212C>T p.R404= | Silent (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- ZNF385A | c.549G>A p.P183= (on ENST00000338010 / NM_001130967.3; = p.P163= on NM_015481.3) | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs779071587; called by muse, mutect2, varscan2
- ZNF536 | c.1482C>A p.L494= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV62817673, COSV62834139; called by muse, mutect2, varscan2
- ARHGAP42 | c.*243G>C | 3'UTR (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- ATAD2B | c.*1894dup | 3'UTR (INS) | VAF 45/126 reads (36%) | called by mutect2, pindel, varscan2
- ATRX | c.*479A>G | 3'UTR (SNP) | VAF 12/17 reads (71%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021268 C>T | 5'Flank (SNP) | VAF 44/100 reads (44%) | catalogued as rs913987622, COSV55850778; called by muse, mutect2, varscan2
- BCL7A | chr12:122021402 C>T | 5'Flank (SNP) | VAF 41/99 reads (41%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, mutect2, varscan2
- C15orf54 | n.427C>T | RNA (SNP) | VAF 10/87 reads (11%) | catalogued as rs770581044; called by muse, mutect2, varscan2
- C2CD3 | c.5881+1065T>G | Intron (SNP) | VAF 91/215 reads (42%) | called by muse, mutect2, varscan2
- CA13 | c.*1557C>A | 3'UTR (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- CCDC198 | c.*1563G>A | 3'UTR (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- CEMIP | c.*2362G>A | 3'UTR (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- CILK1 | c.*456A>T | 3'UTR (SNP) | VAF 70/127 reads (55%) | called by muse, mutect2, varscan2
- COL16A1 | c.3195+18C>T | Intron (SNP) | VAF 35/90 reads (39%) | catalogued as rs1304456716; called by muse, mutect2, varscan2
- CREB5 | c.*5760G>A | 3'UTR (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- CYP4F24P | n.791C>T | RNA (SNP) | VAF 62/324 reads (19%) | catalogued as rs547682452; called by muse, mutect2, varscan2
- DOK4 | c.*861del | 3'UTR (DEL) | VAF 20/78 reads (26%) | called by mutect2, pindel*, varscan2
- DOT1L | c.4606+1244G>A | Intron (SNP) | VAF 57/252 reads (23%) | catalogued as rs1323581161; called by muse, mutect2, varscan2
- E2F7 | c.*931A>C | 3'UTR (SNP) | VAF 68/143 reads (48%) | called by muse, mutect2, varscan2
- ECSIT | c.*2C>G | 3'UTR (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- EIF3A | c.*844_*866del | 3'UTR (DEL) | VAF 10/96 reads (10%) | called by mutect2, pindel
- ETV1 | c.181+402G>T | Intron (SNP) | VAF 410/698 reads (59%) | called by muse, mutect2, varscan2
- FAM217A | c.-87C>T | 5'UTR (SNP) | VAF 15/30 reads (50%) | catalogued as rs527874806; called by muse, mutect2, varscan2
- GLI3 | c.*1496C>T | 3'UTR (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- GLRX2 | chr1:193105915 C>T | 5'Flank (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- GPT2 | c.*1024C>T | 3'UTR (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- GRAMD1B | c.1085-39G>T | Intron (SNP) | VAF 102/215 reads (47%) | called by muse, mutect2, varscan2
- IGHV5-51 | c.-12T>C | 5'UTR (SNP) | VAF 26/89 reads (29%) | catalogued as rs1555541674; called by muse, mutect2, varscan2
- KIAA0586 | c.4450+3751G>T | Intron (SNP) | VAF 52/111 reads (47%) | called by muse, mutect2, varscan2
- KLF6 | c.*1766G>C | 3'UTR (SNP) | VAF 5/70 reads (7%) | catalogued as rs1466107660, COSV51496094; called by muse, mutect2
- LILRB5 | c.1475-122C>T | Intron (SNP) | VAF 4/45 reads (9%) | catalogued as rs548100118; called by muse, mutect2
- LNX1 | c.*245dup | 3'UTR (INS) | VAF 40/131 reads (31%) | catalogued as rs1182549777; called by mutect2, pindel, varscan2
- LRP12 | c.*100del | 3'UTR (DEL) | VAF 44/124 reads (35%) | catalogued as rs1564127019; called by mutect2, pindel, varscan2
- LRRC58 | c.*3655G>A | 3'UTR (SNP) | VAF 19/32 reads (59%) | catalogued as rs1288970257; called by muse, mutect2, varscan2
- MBP | c.576+1001A>G | Intron (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- MOB3B | c.*4332G>A | 3'UTR (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- NFU1 | chr2:69437563 G>A | 5'Flank (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- NLRP12 | chr19:53824386 C>A | 5'Flank (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- OSCAR | c.*949C>T | 3'UTR (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- PARVB | c.712+235C>G | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- PAX5 | c.*1002C>T | 3'UTR (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- PDGFC | c.*748G>T | 3'UTR (SNP) | VAF 64/126 reads (51%) | called by muse, mutect2, varscan2
- PHACTR4 | c.*938C>T | 3'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- PLCXD3 | c.*5095T>C | 3'UTR (SNP) | VAF 59/186 reads (32%) | called by muse, mutect2, varscan2
- PNP | c.461+36G>A | Intron (SNP) | VAF 13/143 reads (9%) | called by muse, mutect2
- PPP1R9A | c.*3669A>G | 3'UTR (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- PRKRA | c.785-120G>T | Intron (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- PSMC1 | c.279+21_279+23del | Intron (DEL) | VAF 29/112 reads (26%) | called by mutect2, pindel, varscan2
- RPE65 | c.*11G>A | 3'UTR (SNP) | VAF 89/309 reads (29%) | called by muse, mutect2, varscan2
- RPS15A | c.*61C>T | 3'UTR (SNP) | VAF 16/139 reads (12%) | catalogued as rs904945052; called by muse, mutect2, varscan2
- S1PR2 | c.-43+743C>G | Intron (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- SCX | c.*193G>A | 3'UTR (SNP) | VAF 7/36 reads (19%) | catalogued as rs894149596; called by muse, mutect2, varscan2
- SH3TC2 | c.279+96G>C | Intron (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- SLC6A14 | c.*105G>A | 3'UTR (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- SLC7A2 | c.*2519C>T | 3'UTR (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- SLC7A2 | c.*3026T>C | 3'UTR (SNP) | VAF 58/119 reads (49%) | called by muse, mutect2, varscan2
- SSR1 | c.*486G>A | 3'UTR (SNP) | VAF 29/195 reads (15%) | catalogued as rs1000794351; called by muse, mutect2, varscan2
- TIMP3 | c.*411T>C | 3'UTR (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2
- TMEFF2 | c.*626G>T | 3'UTR (SNP) | VAF 48/125 reads (38%) | called by muse, mutect2, varscan2
- TMEM182 | c.*1950G>T | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- TNKS | c.673+1582A>T | Intron (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- TP53INP1 | c.*945C>T | 3'UTR (SNP) | VAF 37/100 reads (37%) | called by muse, mutect2, varscan2
- TP73 | c.429+15del | Intron (DEL) | VAF 12/134 reads (9%) | called by mutect2, pindel
- USP49 | c.*1989dup | 3'UTR (INS) | VAF 22/49 reads (45%) | catalogued as rs1225821586; called by mutect2, varscan2
- VGLL3 | c.*2805A>G | 3'UTR (SNP) | VAF 20/33 reads (61%) | catalogued as rs1447622658; called by muse, mutect2, varscan2
- WNT4 | c.313+2536C>T | Intron (SNP) | VAF 6/32 reads (19%) | catalogued as rs543244998; called by muse, mutect2, varscan2
